HCMI case HCM-EXPT-1258-C20 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Rectum. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/4ebd9b62-4c82-412e-b022-c1cea0ff8bd8

Demographics
Sex at birth: female; Days to birth: -26,480 days (72.5 years before the index date).

Diagnoses (2)
1. Basaloid squamous cell carcinoma (the primary disease): ICD-O-3 morphology code: 8083/3; ICD-10 code: C20; Tissue or organ of origin: Rectum, NOS; Classification of tumor: primary; Tumor grade: GX; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Sites of involvement: Liver; Uicc clinical stage: Stage IVA; Uicc pathologic m: M1; Uicc pathologic n: N0; Uicc pathologic stage: Stage IVA; Uicc pathologic t: T1; Uicc staging system edition: 7th.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine + Mitomycin + Oxaliplatin; Treatment intent type: Neoadjuvant; Days to treatment start: 93 days.
   Treatment given: Treatment type: Radiation, 2D Conventional; Treatment intent type: Neoadjuvant; Days to treatment start: 93 days.
2. Squamous cell carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8070/6; ICD-10 code: C78.7; Tissue or organ of origin: Rectum, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis.

Follow-up (1 entry)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (1 sample)
- Sample HCM-EXPT-1258-C20-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
